Gene-level copy-number profile of tumor specimen TCGA-61-1900-01A from TCGA case TCGA-61-1900, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 51.9 years (18,963 days).
Specimen TCGA-61-1900-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a1cff263-34f4-4b99-b038-3089c69c120f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1900-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1cd80c61-c55b-46b8-8945-4c36de606401

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 109; copy number 1: 14,025; copy number 2: 30,005; copy number 3: 13,293; copy number 4: 1,726; copy number 5: 127; copy number 6: 397; copy number 7: 134.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1900-01A-01D-0577-01): tumor purity 0.9, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 108 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:6,572,571–6,708,224, 4 genes (within-gene range 0–1): AC018398.2, AF287957.1, MCPH1-AS1, MIR8055.
- chr9:17,134,982–17,503,923, 2 genes (within-gene range 0–1): CNTLN, SAMM50P1.
- chr9:20,331,446–23,438,700, 70 genes (within-gene range 0–1) (broad region; genes not listed).
- chr17:64,953,683–66,895,572, 25 genes: SLC16A6P1, AMZ2P1, GNA13, AC037487.2, RGS9, AC060771.1, LINC02563, AXIN2, AC004805.1, CEP112, AC004805.3, AC004805.2, PSMD7P1, APOH, RNA5SP444, AC009452.1, PRKCA, RN7SL735P, PRKCA-AS1, RNU6-928P, RNA5SP445, AC006947.1, MIR634, CACNG5, RNA5SP446.
- chr20:14,884,250–15,619,819, 7 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 658 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:155,375,580–192,917,856, 586 genes, copy number 5–7 (broad region; genes not listed).
- chr7:145,269,514–146,050,366, 4 genes, copy number 5: AC004911.1, DPY19L4P2, AC006007.1, AC073308.1.
- chr11:25,588,475–28,683,469, 38 genes, copy number 5: RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1, ANO3, AC021698.1, ANO3-AS1, AC079064.1, MUC15, SLC5A12, FIBIN, BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF, AC103796.1, CBX3P1, HSP90AA2P, AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758.
- chr12:66,767–1,504,424, 30 genes, copy number 5: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942.

Autosomal genes at a single copy (total copy number 1): 12,662. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
